Somatic mutation profile of tumor specimen TCGA-69-7765-01A (aliquot TCGA-69-7765-01A-11D-2167-08) from TCGA case TCGA-69-7765, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 56.5 years (20,625 days).
Specimen TCGA-69-7765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6318ffec-28c2-4307-9db8-38bf7f13cd12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7765-10A (Blood Derived Normal), aliquot TCGA-69-7765-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9291f6e-283f-434b-ad5a-d498ef81532a

The open-access MAF lists 653 somatic variants for this specimen: 483 protein-altering or splice-affecting, 159 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 424, Silent 159, Nonsense Mutation 36, Frame Shift Del 11, Splice Site 7, RNA 7, Intron 3, Splice Region 2, 5'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV62789641; called by muse, mutect2, varscan2
- ABCB8 | c.1008G>T p.E336D (on ENST00000297504 / NM_001282291.2; = p.E319D on NM_007188.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52503752; called by mutect2, varscan2
- ABCC4 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65311586; called by muse, mutect2, varscan2
- ACACB | c.3470G>T p.R1157M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100623427; called by muse, mutect2
- ACACB | c.3471G>T p.R1157S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100623428; called by muse, mutect2, varscan2
- ACCS | c.1382C>G p.S461* | Nonsense Mutation (SNP) | VAF 5/103 reads (5%) | catalogued as COSV55457836; called by muse, mutect2
- ACOT12 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV56894284; called by muse, mutect2, varscan2
- ACSM1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV54634722; called by muse, mutect2, varscan2
- ACSM6 | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58978102; called by muse, mutect2, varscan2
- ACTL6A | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV66998857; called by muse, mutect2, varscan2
- ADAM20 | c.998T>A p.L333* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV56454672; called by muse, mutect2, varscan2
- ADAM29 | c.23A>T p.H8L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV63662566; called by muse, mutect2, varscan2
- ADAM8 | c.589C>G p.R197G | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV101291628, COSV101291689, COSV69864525; called by muse, mutect2, varscan2
- ADAMTS12 | c.4254C>A p.S1418R | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.296); catalogued as COSV61260511; called by muse, mutect2, varscan2
- ADAMTS20 | c.5063C>A p.S1688Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV101240741; called by muse, mutect2, varscan2
- ADAMTS9 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55779166; called by muse, mutect2, varscan2
- ADCY8 | c.1751C>G p.T584S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV53903809; called by muse, mutect2, varscan2
- ADCY8 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV53903824; called by muse, mutect2, varscan2
- ADGRG4 | c.8315G>T p.R2772L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs781632638, COSV54953743, COSV54956645; called by muse, mutect2, varscan2
- ALKBH3 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV57023700, COSV57026024; called by muse, mutect2, varscan2
- ANKMY1 | c.1449G>T p.Q483H | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV56032735; called by muse, mutect2, varscan2
- ANKMY1 | c.319A>T p.T107S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV56032767; called by muse, mutect2, varscan2
- ANKRD30A | c.3399T>G p.F1133L (on ENST00000611781; = p.F1077L on NM_052997.2) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV64608301; called by muse, mutect2, varscan2
- AOC3 | c.1455A>G p.I485M | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as COSV53825761; called by muse, mutect2, varscan2
- AP002512.3 | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.596); catalogued as COSV54406212; called by muse, mutect2, varscan2
- APP | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV60997231; called by muse, mutect2, varscan2
- ARFGEF3 | c.966C>G p.I322M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV52454941; called by muse, mutect2, varscan2
- ARHGAP24 | c.449G>T p.R150L (on ENST00000395184 / NM_001025616.3; = p.R57L on NM_031305.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV51988305; called by muse, mutect2, varscan2
- ARHGEF25 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54085836; called by muse, mutect2
- ARPP21 | c.2206G>A p.G736R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV51792914; called by muse, mutect2
- ASPSCR1 | c.345G>C p.W115C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60728204, COSV60731124; called by muse, mutect2, varscan2
- ASTN1 | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56066458; called by muse, mutect2, varscan2
- ASTN2 | c.1590C>A p.T530= (on ENST00000313400 / NM_001365069.1; = p.T479= on NM_014010.5) | Splice Region (SNP) | VAF 20/82 reads (24%) | catalogued as COSV57769233, COSV57772604; called by muse, mutect2, varscan2
- ATP8A1 | c.1207-1G>T p.X403_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52532732; called by muse, mutect2, varscan2
- ATRNL1 | c.3136G>A p.G1046S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58082778; called by muse, mutect2, varscan2
- AUH | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV57862656; called by muse, mutect2, varscan2
- AXDND1 | c.2998T>A p.S1000T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV100858769; called by muse, mutect2
- BAAT | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as rs775869688, COSV52288131, COSV52291261; called by muse, mutect2, varscan2
- BCAM | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54301686; called by muse, mutect2, varscan2
- BCHE | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52255650; called by muse, mutect2
- BCL11A | c.2207A>G p.Y736C (on ENST00000335712 / NM_001365609.1; = p.Y770C on NM_022893.4) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59627990; called by muse, mutect2, varscan2
- BCL9 | c.4117G>A p.G1373R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as COSV52342981; called by muse, mutect2, varscan2
- BEND3 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.12); catalogued as COSV64680796; called by muse, mutect2, varscan2
- BICC1 | c.2857G>T p.G953C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV65858408; called by muse, mutect2, varscan2
- BMI1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64958915; called by muse, mutect2, varscan2
- BOP1 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs768626008, COSV56639324; called by muse, mutect2, varscan2
- BRINP2 | c.2052G>T p.Q684H | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV64176919; called by muse, mutect2, varscan2
- BRINP3 | c.1365C>A p.D455E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.577); catalogued as COSV66520136; called by muse, mutect2, varscan2
- BTAF1 | c.1480A>G p.M494V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV56432031; called by muse, mutect2, varscan2
- BTN1A1 | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); catalogued as COSV55067270; called by muse, mutect2, varscan2
- C12orf45 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99774087; called by muse, mutect2
- C19orf18 | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV58705626; called by muse, mutect2, varscan2
- C1orf116 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63943951; called by muse, mutect2, varscan2
- C8B | c.497T>C p.M166T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV64777299; called by muse, mutect2, varscan2
- CACNA1E | c.3330G>T p.E1110D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV62389966; called by muse, mutect2, varscan2
- CADM4 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55928546; called by muse, mutect2, varscan2
- CAMLG | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.585); catalogued as COSV51804506; called by muse, mutect2, varscan2
- CARMIL3 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57725879; called by muse, mutect2
- CASP8AP2 | c.4726G>T p.A1576S | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV52746344; called by muse, mutect2, varscan2
- CCDC121 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV53114044; called by muse, mutect2
- CCDC54 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV53758427; called by muse, mutect2, varscan2
- CCKBR | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58100403; called by muse, mutect2, varscan2
- CD79A | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as COSV55738434; called by muse, mutect2
- CDC37 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV55767986; called by muse, mutect2, varscan2
- CDH10 | c.1072C>A p.R358S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV52572321; called by muse, mutect2, varscan2
- CDH9 | c.1580C>A p.P527Q | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV50268814; called by muse, mutect2
- CDK6 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.078); catalogued as COSV56006965; called by muse, mutect2, varscan2
- CENPH | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV51584652; called by muse, mutect2, varscan2
- CEP250 | c.4623G>C p.Q1541H | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61168942; called by muse, mutect2
- CEP72 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV53791800; called by muse, mutect2, varscan2
- CHD5 | c.913A>T p.S305C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52412332; called by muse, mutect2, varscan2
- CHGB | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV66760140; called by muse, mutect2, varscan2
- CHL1 | c.3114G>T p.E1038D (on ENST00000397491 / NM_001253387.1; = p.E1054D on NM_006614.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56590874; called by muse, mutect2, varscan2
- CNTN5 | c.1264C>A p.R422S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.601); catalogued as rs759583728, COSV54276146, COSV54301200; called by muse, mutect2, varscan2
- CNTNAP4 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100273808; called by muse, mutect2, varscan2
- CNTNAP4 | c.3798G>T p.Q1266H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV56674875; called by muse, mutect2, varscan2
- COL20A1 | c.3420G>T p.E1140D | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV58915065; called by muse, mutect2, varscan2
- COL7A1 | c.4706G>T p.G1569V | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60394022; called by muse, mutect2, varscan2
- COL7A1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs147470888; called by muse, mutect2, varscan2
- COQ5 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV56018809; called by muse, mutect2, varscan2
- CRYGC | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52205075; called by muse, mutect2, varscan2
- CSMD3 | c.6358G>C p.G2120R (on ENST00000297405 / NM_001363185.1; = p.G2016R on NM_052900.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52153136; called by muse, mutect2, varscan2
- CSMD3 | c.3920T>C p.L1307P (on ENST00000297405 / NM_001363185.1; = p.L1203P on NM_052900.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52153158; called by muse, mutect2, varscan2
- CTNNA3 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57718694; called by muse, mutect2, varscan2
- CYB561D1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV60204327; called by muse, mutect2, varscan2
- DAB2 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV57913753; called by muse, mutect2, varscan2
- DAP | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV50143543; called by muse, mutect2
- DENND2A | c.1966G>A p.G656S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758642466, COSV52050104; called by muse, mutect2, varscan2
- DHX32 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52939538; called by muse, mutect2, varscan2
- DIAPH2 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61265821; called by muse, mutect2, varscan2
- DLG5 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV64947579; called by muse, mutect2, varscan2
- DLGAP3 | c.2171C>A p.T724N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV52393205; called by muse, mutect2, varscan2
- DMD | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55864847; called by muse, mutect2
- DNAH3 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54515569; called by muse, mutect2, varscan2
- DNAI2 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56758027; called by muse, mutect2, varscan2
- DNPEP | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV56110592; called by muse, mutect2, varscan2
- DOCK10 | c.5809C>A p.P1937T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV51373559; called by muse, mutect2
- DOCK2 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV56953141; called by muse, mutect2, varscan2
- DOCK2 | c.5231A>T p.K1744M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); catalogued as COSV56944552; called by muse, mutect2, varscan2
- DPF3 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); catalogued as COSV63499699; called by muse, mutect2, varscan2
- DPP6 | c.1585T>C p.S529P (on ENST00000377770 / NM_001364500.2; = p.S467P on NM_001936.5) | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59607217; called by muse, mutect2, varscan2
- DPP6 | c.2301C>A p.Y767* (on ENST00000377770 / NM_001364500.2; = p.Y705* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 44/340 reads (13%) | catalogued as COSV59607232, COSV59626592; called by muse, mutect2, varscan2
- DQX1 | c.2132G>A p.R711K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1435036642, COSV52045658; called by muse, mutect2, varscan2
- DUOX2 | c.2465T>A p.M822K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV66531516; called by muse, mutect2
- DUSP22 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.143); catalogued as COSV60525832; called by muse, mutect2, varscan2
- DYSF | c.1906C>G p.Q636E | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV50294314; called by muse, mutect2
- DZIP3 | c.1184A>T p.H395L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV64311695, COSV64311740; called by muse, mutect2, varscan2
- EED | c.1231G>C p.A411P | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV54554751; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56181740; called by muse, mutect2, varscan2
- EGFR | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV51790518; called by muse, mutect2, varscan2
- ELOA2 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV55297199; called by muse, mutect2, varscan2
- ELOVL4 | c.336T>G p.S112R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1360351259, COSV63953670; called by muse, mutect2, varscan2
- EML4 | c.2378A>G p.N793S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771053246, COSV59296296; called by muse, mutect2, varscan2
- ENOX1 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); catalogued as COSV54895464; called by muse, mutect2, varscan2
- EPHA10 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs771803475, COSV60402406; called by muse, mutect2
- ERCC4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as rs1383959352, COSV61311570; called by muse, mutect2, varscan2
- ERO1B | c.673+1G>T p.X225_splice | Splice Site (SNP) | VAF 31/65 reads (48%) | catalogued as COSV59242066; called by muse, mutect2, varscan2
- ESCO1 | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV52519256; called by mutect2, varscan2
- FAM136A | c.259A>T p.N87Y | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV50682556; called by muse, mutect2, varscan2
- FAM153B | c.716A>T p.E239V (on ENST00000253490; = p.E162V on NM_001265615.1) | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); catalogued as COSV53686135; called by muse, mutect2
- FAM153B | c.718G>T p.D240Y (on ENST00000253490; = p.D163Y on NM_001265615.1) | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.843); catalogued as COSV53686145; called by muse, mutect2
- FAM171B | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV59002516; called by muse, mutect2
- FAM171B | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV59002526, COSV59006666; called by muse, mutect2, varscan2
- FAM237A | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101405611; called by muse, mutect2
- FAU | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54194440; called by muse, mutect2, varscan2
- FBXL18 | c.341A>C p.H114P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as COSV66666150; called by muse, varscan2
- FBXL4 | c.1865G>T p.*622Lext*16 | Nonstop Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV57746401; called by muse, mutect2, varscan2
- FGB | c.992A>T p.Q331L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs976144403, COSV57418009; called by muse, mutect2, varscan2
- FGD1 | c.1486C>G p.H496D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV64308536; called by muse, mutect2, varscan2
- FGFR4 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV52802466; called by muse, mutect2, varscan2
- FLG | c.5395G>A p.D1799N | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs1322374691, COSV100911673, COSV64240228; called by muse, mutect2
- FLG | c.4072G>A p.G1358R | Missense Mutation (SNP) | VAF 137/1147 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV64240239; called by muse, mutect2, varscan2
- FLRT3 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV53970711; called by muse, mutect2, varscan2
- FMN2 | c.3131C>A p.P1044Q | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.111); catalogued as COSV100146264, COSV60426498, COSV60438124; called by muse, varscan2
- FRMPD1 | c.4700G>C p.C1567S | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66700017; called by muse, mutect2, varscan2
- FRMPD2 | c.2287A>T p.K763* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV59717108; called by muse, mutect2, varscan2
- FUT9 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56145232; called by muse, mutect2, varscan2
- GABRB3 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV54659383; called by muse, mutect2, varscan2
- GABRB3 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); catalogued as COSV54659442; called by muse, varscan2
- GALNT18 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV57147275; called by muse, mutect2
- GATD1 | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60591955, COSV60593570; called by muse, mutect2, varscan2
- GBP5 | c.27C>A p.D9E | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs374743187, COSV58592273; called by muse, mutect2, varscan2
- GJB2 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275901105, CD051751, COSV67010661; called by muse, mutect2, varscan2
- GLI3 | c.4292C>A p.P1431Q | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV67887381; called by muse, varscan2
- GOLGA3 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.062); catalogued as COSV52629090; called by muse, mutect2, varscan2
- GPR176 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761921765, COSV54444486; called by muse, mutect2, varscan2
- GPR45 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775474130, COSV51523402; called by muse, varscan2
- GPR45 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51523420, COSV99307332; called by muse, varscan2
- GPR50 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV54436997; called by muse, mutect2, varscan2
- GPRC6A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.033); catalogued as COSV59952540; called by muse, mutect2
- GPT2 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV60838122; called by muse, mutect2, varscan2
- GRIA3 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52055889; called by muse, mutect2, varscan2
- H3C6 | c.11C>G p.T4S | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1172336068, COSV64519529; called by muse, mutect2
- HDAC9 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV67771191; called by muse, mutect2, varscan2
- HDHD5 | c.928G>T p.A310S (on ENST00000336737 / NM_033070.3; = p.A280S on NM_017829.5) | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV50085129; called by muse, mutect2, varscan2
- HECW2 | c.1303A>T p.T435S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV53655983, COSV53664336; called by muse, mutect2, varscan2
- HHAT | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV54796409; called by muse, mutect2, varscan2
- HNRNPA1 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV99268021; called by muse, mutect2, varscan2
- HRNR | c.2410T>A p.C804S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64256726; called by muse, mutect2
- HTR5A | c.742-1G>T p.X248_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55282200; called by muse, mutect2, varscan2
- IFNL3 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV69829906; called by muse, mutect2, varscan2
- IGF2BP2 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV60482565, COSV60484841; called by muse, mutect2, varscan2
- IGKV3-11 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs767194893; called by muse, mutect2, varscan2
- IGSF10 | c.6101G>T p.R2034I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV56375423; called by muse, mutect2, varscan2
- IL23R | c.1567A>T p.R523W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.724); catalogued as COSV61373899; called by muse, mutect2, varscan2
- IMPG1 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.91); catalogued as COSV64056704; called by muse, mutect2
- INHBE | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56987879; called by muse, mutect2, varscan2
- INO80D | c.2210G>C p.R737P | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.103); catalogued as COSV68958624; called by muse, mutect2, varscan2
- INO80D | c.974G>C p.W325S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV68958629; called by muse, mutect2, varscan2
- INO80D | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV68958633; called by muse, mutect2, varscan2
- IRF4 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV66704501, COSV66704941; called by muse, mutect2
- IRF8 | c.511A>T p.S171C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV51897571; called by muse, mutect2, varscan2
- ISLR2 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100679849; called by muse, varscan2
- ITGA8 | c.3122G>T p.R1041I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65227309; called by muse, mutect2, varscan2
- ITGAM | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54936125; called by muse, mutect2, varscan2
- JAG1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV54755794; called by muse, mutect2, varscan2
- JAM3 | c.340C>A p.R114S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54452029, COSV54453223; called by mutect2, varscan2
- KALRN | c.8732C>A p.A2911D (on ENST00000360013 / NM_001024660.4; = p.A1214D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52254517; called by muse, mutect2, varscan2
- KBTBD7 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV101068237; called by muse, mutect2, varscan2
- KCNA4 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60251639; called by muse, mutect2
- KCNA4 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as COSV60251648; called by muse, mutect2
- KCNH3 | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV57790341; called by muse, mutect2, varscan2
- KCNK2 | c.897C>A p.Y299* (on ENST00000444842 / NM_001017425.3; = p.Y284* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 33/322 reads (10%) | catalogued as COSV67204850; called by muse, mutect2, varscan2
- KCNT2 | c.3151G>T p.E1051* | Nonsense Mutation (SNP) | VAF 46/97 reads (47%) | catalogued as COSV54074221; called by muse, mutect2, varscan2
- KCTD19 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58572261; called by muse, mutect2, varscan2
- KEL | c.2009A>C p.Q670P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV62334333; called by muse, mutect2
- KIAA1109 | c.9646G>A p.A3216T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52668866; called by muse, mutect2, varscan2
- KIF14 | c.4706A>T p.Q1569L | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV66261210; called by muse, mutect2, varscan2
- KIF16B | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100733648, COSV61704744; called by muse, mutect2, varscan2
- KLHL1 | c.816A>C p.T272= | Splice Region (SNP) | VAF 13/74 reads (18%) | catalogued as rs763233627, COSV64770457; called by muse, mutect2, varscan2
- KLHL42 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67145800; called by muse, mutect2, varscan2
- KLK3 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58099900; called by muse, mutect2, varscan2
- KRT74 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0.107); catalogued as rs759164117, COSV59770752; called by muse, mutect2, varscan2
- KRT75 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV52872057; called by muse, mutect2, varscan2
- KRT85 | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs758865856, COSV57736541; called by muse, mutect2, varscan2
- KRTAP19-8 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66998368; called by muse, mutect2, varscan2
- KSR1 | c.2417C>T p.A806V (on ENST00000644974 / NM_001367810.1; = p.A691V on NM_014238.2) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV52030809; called by muse, mutect2, varscan2
- KTN1 | c.3572G>T p.R1191L (on ENST00000395314 / NM_001271014.2; = p.R1162L on NM_004986.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs756191445, COSV58540204; called by muse, mutect2, varscan2
- LAMA5 | c.10810C>T p.Q3604* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as rs762380026, COSV53357825; called by muse, mutect2, varscan2
- LAMB4 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV52717302, COSV52723351; called by muse, mutect2, varscan2
- LMBRD1 | c.961G>T p.G321C (on ENST00000649011; = p.G299C on NM_018368.4) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV65296831; called by muse, mutect2, varscan2
- LRFN5 | c.2144G>T p.R715M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV53251698; called by muse, mutect2, varscan2
- LRP4 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV66135280; called by muse, mutect2, varscan2
- LRRTM4 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139699; called by muse, mutect2, varscan2
- LTBP1 | c.2976G>T p.Q992H (on ENST00000404816 / NM_206943.4; = p.Q666H on NM_000627.4) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs1285332124, COSV63184461; called by muse, mutect2, varscan2
- LUZP1 | c.1756A>C p.N586H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV56500330; called by muse, mutect2, varscan2
- MAEL | c.854G>C p.W285S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63304802; called by muse, mutect2, varscan2
- MAP1S | c.2992G>T p.A998S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.199); catalogued as COSV60722310; called by muse, mutect2
- MAP2 | c.3610A>T p.S1204C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV52287603; called by muse, mutect2
- MAP2K4 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62256549; called by muse, mutect2, varscan2
- MAP7 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63418870; called by muse, mutect2, varscan2
- MCM6 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1558764542, COSV51465761; called by muse, mutect2, varscan2
- MFSD9 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV51493188; called by mutect2, varscan2
- MIA2 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54491591; called by muse, mutect2, varscan2
- MIF4GD | c.368T>A p.M123K (on ENST00000325102 / NM_001370592.1; = p.M157K on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV55453259; called by muse, mutect2, varscan2
- MRAP2 | c.186del p.F62Lfs*3 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs758625941; called by mutect2, pindel, varscan2
- MRPL10 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV51619753; called by muse, mutect2, varscan2
- MUC16 | c.9761G>T p.S3254I | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV67459230; called by muse, mutect2, varscan2
- MUC5B | c.7946C>A p.P2649H | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs748618196, COSV71591317; called by muse, mutect2, varscan2
- MUC7 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.41); catalogued as rs760535115, COSV59217949; called by muse, mutect2, varscan2
- MYO18B | c.7291C>A p.L2431I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59131192; called by muse, mutect2, varscan2
- MYO7B | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101268446; called by muse, mutect2, varscan2
- MYOM2 | c.175A>T p.S59C | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV50707983; called by muse, mutect2, varscan2
- MYOM3 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV58392629; called by muse, mutect2, varscan2
- NALCN | c.2566G>T p.A856S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.395); catalogued as COSV51929109; called by muse, mutect2, varscan2
- NAV3 | c.4185G>C p.E1395D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.914); catalogued as COSV57073782; called by muse, mutect2, varscan2
- NCAM1 | c.1290C>A p.N430K (on ENST00000316851 / NM_181351.5; = p.N420K on NM_000615.7) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57514276; called by muse, mutect2, varscan2
- NCAN | c.2722C>T p.Q908* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV53049750; called by muse, mutect2, varscan2
- NCOA6 | c.1089A>C p.L363F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62862784; called by muse, mutect2, varscan2
- NEB | c.7225G>C p.E2409Q | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51101250; called by muse, mutect2
- NES | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.832); catalogued as COSV63960750; called by muse, mutect2, varscan2
- NETO2 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV57452315; called by muse, mutect2, varscan2
- NF1 | c.6070G>T p.G2024* (on ENST00000358273 / NM_001042492.3; = p.G2003* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV62199782; called by muse, mutect2, varscan2
- NF1 | c.8114-1G>T p.X2705_splice (on ENST00000358273 / NM_001042492.3; = p.X2684_splice on NM_000267.3) | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62225147; called by muse, mutect2
- NF1 | c.8114G>T p.S2705I (on ENST00000358273 / NM_001042492.3; = p.S2684I on NM_000267.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV100648545; called by muse, mutect2
- NID2 | c.1776G>T p.W592C | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53495001; called by muse, mutect2, varscan2
- NLGN4X | c.2369A>T p.Q790L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); catalogued as COSV52013177; called by muse, mutect2, varscan2
- NLRC5 | c.2834C>G p.A945G | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV52653386; called by muse, mutect2, varscan2
- NLRP13 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV100738683; called by muse, mutect2, varscan2
- NOL9 | c.1959+1G>T p.X653_splice | Splice Site (SNP) | VAF 13/104 reads (13%) | catalogued as COSV66625744; called by muse, mutect2, varscan2
- NOM1 | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV99316205; called by muse, mutect2, varscan2
- NOM1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV51982066; called by muse, mutect2, varscan2
- NOS1AP | c.1446G>T p.E482D | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV62633887; called by muse, mutect2, varscan2
- NOTCH2 | c.4834G>A p.G1612S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56688495; called by muse, mutect2, varscan2
- NPHP3 | c.2052A>T p.E684D | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV58629384; called by muse, mutect2, varscan2
- NPHS1 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62287337; called by muse, mutect2, varscan2
- NSG1 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60372635; called by muse, mutect2, varscan2
- NT5C1B | c.550C>T p.Q184* (on ENST00000359846 / NM_001199086.2; = p.Q124* on NM_033253.4) | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58395365; called by muse, mutect2, varscan2
- NT5DC1 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV60307775; called by muse, mutect2, varscan2
- NTSR1 | c.1153G>T p.V385L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65138385; called by muse, mutect2, varscan2
- NUBP1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148166867, COSV51593302; called by muse, mutect2, varscan2
- NUP210 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54405047; called by muse, mutect2, varscan2
- NUTM1 | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100149268; called by muse, mutect2, varscan2
- NUTM1 | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100149275; called by muse, mutect2, varscan2
- NYAP2 | c.478A>T p.S160C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV56002895; called by muse, mutect2, varscan2
- OR11H1 | c.704G>T p.S235I | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs751642754, COSV53271819; called by muse, mutect2, varscan2
- OR2AK2 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); catalogued as COSV63551638; called by muse, mutect2
- OR2B11 | c.433T>G p.C145G | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59509879; called by muse, mutect2
- OR2C3 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63574811; called by muse, mutect2, varscan2
- OR2L13 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 35/484 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63550000, COSV63551649; called by muse, mutect2
- OR2L13 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV63551658, COSV63551939; called by muse, mutect2, varscan2
- OR2M2 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62897826, COSV62898145; called by muse, varscan2
- OR2M2 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62898044, COSV62898149; called by muse, varscan2
- OR2M3 | c.353T>A p.M118K | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV71758984; called by muse, mutect2, varscan2
- OR2T2 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV100737836; called by mutect2, varscan2
- OR2T8 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs1214727324; called by muse, mutect2, varscan2
- OR2W3 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 27/346 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV64456620; called by muse, mutect2
- OR4C13 | c.540C>A p.Y180* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | catalogued as COSV73648716; called by muse, mutect2, varscan2
- OR52K1 | c.645T>G p.F215L | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.036); catalogued as COSV56903516; called by muse, mutect2, varscan2
- OR52L1 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176425; called by muse, mutect2, varscan2
- OR5B2 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV56907992; called by muse, mutect2, varscan2
- OR5D13 | c.140T>G p.M47R | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV62333414; called by muse, mutect2, varscan2
- OR5H2 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV62350553; called by muse, mutect2, varscan2
- OR5M10 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1295843473, COSV73242287; called by muse, mutect2, varscan2
- OR5T2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57588702; called by muse, mutect2, varscan2
- OR6T1 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58306478; called by muse, mutect2, varscan2
- OR7C2 | c.457G>T p.V153F | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.097); catalogued as COSV50180431; called by muse, mutect2, varscan2
- OTOA | c.1648G>T p.D550Y (on ENST00000286149; = p.D536Y on NM_144672.4) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV53752172; called by muse, mutect2, varscan2
- OTOF | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55500800; called by muse, mutect2, varscan2
- OTOP1 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56392412; called by muse, mutect2, varscan2
- OTOP3 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV60912875, COSV60913449; called by muse, mutect2
- P3H4 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100388060; called by muse, mutect2
- PAK3 | c.322G>T p.G108* (on ENST00000262836 / NM_001324328.2; = p.G93* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as COSV53273151; called by muse, mutect2, varscan2
- PAQR5 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.291); catalogued as COSV61817773; called by muse, mutect2, varscan2
- PCDH11X | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53457475; called by muse, mutect2, varscan2
- PCDH15 | c.2476G>C p.V826L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV57291907; called by muse, mutect2, varscan2
- PCDH7 | c.3182T>C p.L1061P | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV62337900; called by muse, mutect2
- PCDHB10 | c.2194G>T p.G732C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as rs782273215, COSV53377684; called by muse, mutect2, varscan2
- PCNX1 | c.4572C>G p.D1524E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV53092821; called by muse, mutect2, varscan2
- PCNX1 | c.6860G>T p.S2287I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV53092834; called by muse, mutect2
- PDE4DIP | c.3325C>A p.L1109M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57690134; called by mutect2, varscan2
- PEG3 | c.3259C>A p.P1087T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV99690959; called by muse, mutect2, varscan2
- PGR | c.139del p.E47Kfs*119 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | catalogued as COSV54812363; called by mutect2, pindel
- PICK1 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV63659994; called by muse, mutect2
- PIK3R4 | c.3616G>T p.G1206C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100651125; called by muse, mutect2
- PKD1L2 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV61414109; called by muse, mutect2, varscan2
- PLA2G4A | c.954A>T p.K318N | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV66553286; called by muse, mutect2, varscan2
- PLBD2 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55106389; called by muse, mutect2
- PLCB1 | c.1964T>C p.M655T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62046508; called by muse, mutect2, varscan2
- PLCE1 | c.3013C>G p.L1005V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV53346092; called by muse, mutect2, varscan2
- PLPPR4 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100926887, COSV64565344; called by muse, mutect2, varscan2
- PNPT1 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99570656; called by muse, mutect2
- POPDC2 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1403648790, COSV51740437; called by muse, mutect2, varscan2
- PPBP | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56019690, COSV56019924; called by muse, mutect2, varscan2
- PPFIA3 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566360934, COSV61950895; called by muse, mutect2, varscan2
- PPP1CB | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.089); catalogued as COSV99942026; called by muse, mutect2, varscan2
- PPP3R1 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99310677; called by muse, mutect2
- PRDM14 | c.1348C>A p.H450N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52571672; called by muse, mutect2, varscan2
- PRDM14 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as rs750600524, COSV52571688; called by muse, mutect2, varscan2
- PROKR1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58137205; called by muse, mutect2, varscan2
- PROSER3 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56553154, COSV56554829; called by muse, mutect2, varscan2
- PRRC2B | c.5512A>T p.R1838W | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV57644904; called by muse, mutect2, varscan2
- PRRC2C | c.2938G>A p.G980R (on ENST00000367742; = p.G978R on NM_015172.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV58903862; called by muse, mutect2, varscan2
- PRSS38 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs1282229532, COSV64540140; called by muse, mutect2
- PRUNE2 | c.88T>A p.C30S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65027329; called by muse, mutect2
- PTCHD4 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV59781864; called by muse, mutect2, varscan2
- PTPRC | c.3428T>C p.V1143A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV61409592; called by muse, mutect2, varscan2
- PTPRD | c.3542G>C p.R1181P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61928613, COSV61938527, COSV61976608; called by muse, mutect2, varscan2
- PUS7 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 23/168 reads (14%) | catalogued as COSV62676444; called by muse, mutect2, varscan2
- PXDNL | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62485189; called by muse, mutect2, varscan2
- QRICH2 | c.3085G>C p.E1029Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53152410, COSV53152605; called by muse, mutect2
- RAD23B | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63658140; called by mutect2, varscan2
- RALGPS1 | c.1488G>T p.W496C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52220198; called by muse, mutect2, varscan2
- RANBP2 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51699360; called by muse, mutect2, varscan2
- RASSF4 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as COSV58485697; called by muse, mutect2, varscan2
- RBM27 | c.2323G>C p.D775H | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.423); catalogued as COSV54589028; called by muse, mutect2
- RBP1 | c.157C>T p.R53C (on ENST00000619087 / NM_001365940.2; = p.R115C on NM_002899.5) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs748057243, COSV51676323; called by muse, mutect2
- RC3H1 | c.953A>T p.Q318L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51199413; called by muse, mutect2, varscan2
- RCOR1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51767328; called by muse, mutect2, varscan2
- REG3A | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs960792179, COSV59409171; called by muse, mutect2, varscan2
- RFC4 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV56216560; called by muse, mutect2, varscan2
- RGP1 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV65239298, COSV65239971; called by muse, mutect2, varscan2
- RGS18 | c.543T>A p.Y181* | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | catalogued as COSV66507758; called by muse, mutect2, varscan2
- RICTOR | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV57120491; called by muse, mutect2, varscan2
- RP1L1 | c.5299G>T p.A1767S | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV66754057; called by muse, mutect2, varscan2
- RP1L1 | c.5078T>C p.L1693P | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66754063; called by muse, mutect2, varscan2
- RSPH6A | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs377543353, COSV55574864, COSV99680221; called by muse, mutect2
- RTL3 | c.1257C>A p.N419K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV58183822; called by muse, mutect2, varscan2
- RTN1 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV50721426; called by muse, mutect2, varscan2
- RYR1 | c.9453G>T p.Q3151H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV62094525; called by muse, mutect2, varscan2
- RYR2 | c.12480G>T p.W4160C | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63678554; called by muse, mutect2
- RYR3 | c.594G>C p.M198I | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV66784676, COSV66794202; called by muse, mutect2, varscan2
- RYR3 | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV66784682; called by muse, mutect2, varscan2
- RYR3 | c.13462C>A p.L4488I (on ENST00000389232; = p.L4489I on NM_001036.6) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV66784688; called by muse, mutect2, varscan2
- SAAL1 | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV55515324; called by muse, mutect2
- SAMD3 | c.1301T>C p.L434S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV62385478; called by muse, mutect2
- SAMD7 | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | catalogued as COSV59418128; called by muse, mutect2, varscan2
- SCN10A | c.2598C>A p.C866* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV71860963; called by muse, mutect2, varscan2
- SCN10A | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as rs747174454, COSV71860964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs199473142, CM070260, COSV61121343; ClinVar: not provided / likely benign; called by muse, mutect2, varscan2
- SCNN1B | c.68A>T p.K23M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56303423; called by muse, mutect2, varscan2
- SEC14L3 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53178776, COSV53179631; called by muse, mutect2, varscan2
- SELENBP1 | c.1408A>C p.I470L | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774554029, COSV64373005, COSV64373295; called by muse, mutect2, varscan2
- SEMA3D | c.1283A>C p.Y428S | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV52391403, COSV52397481; called by muse, mutect2, varscan2
- SF3B4 | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.987); catalogued as COSV54965022; called by muse, mutect2
- SGIP1 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as rs1359709055, COSV52766291; called by muse, mutect2, varscan2
- SHOX | c.567C>A p.N189K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV61860617; called by muse, mutect2, varscan2
- SIRPA | c.684C>A p.C228* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV61537898; called by muse, mutect2, varscan2
- SLC24A2 | c.1280C>A p.S427Y | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV53862527; called by muse, mutect2, varscan2
- SLC25A6 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV58430767, COSV58431072; called by muse, varscan2
- SLC27A6 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs762163187, COSV52482124, COSV52483190; called by muse, mutect2, varscan2
- SLC2A12 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV51599459; called by muse, mutect2, varscan2
- SLC4A4 | c.1728G>T p.L576F (on ENST00000264485 / NM_001098484.3; = p.L532F on NM_003759.4) | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52621379; called by muse, mutect2, varscan2
- SLC5A7 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as COSV50890528; called by muse, mutect2, varscan2
- SLC6A19 | c.1034T>A p.I345N | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV58670710; called by muse, mutect2, varscan2
- SLCO5A1 | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52663836, COSV99481410; called by muse, mutect2, varscan2
- SLIT3 | c.2771C>A p.P924Q | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60596867, COSV60603101; called by muse, mutect2, varscan2
- SMAD4 | c.298A>T p.R100W | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61686044, COSV61686952; called by muse, mutect2, varscan2
- SMARCB1 | c.431G>T p.R144L (on ENST00000263121; = p.R190L on NM_003073.5) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54095663, COSV54101964; called by muse, mutect2, varscan2
- SMG5 | c.2537A>T p.Q846L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV52744869; called by muse, mutect2
- SMTN | c.1633-1G>C p.X545_splice | Splice Site (SNP) | VAF 5/68 reads (7%) | catalogued as COSV60777341; called by muse, mutect2
- SPAG17 | c.1103G>C p.S368T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.273); catalogued as COSV60456696, COSV60462464; called by muse, mutect2, varscan2
- SPATA31D1 | c.3818G>T p.R1273M | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV61194678; called by muse, mutect2, varscan2
- SPO11 | c.675del p.D226Mfs*8 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1568760216; called by mutect2, pindel, varscan2
- SPTA1 | c.3127C>T p.P1043S | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63751657; called by muse, mutect2, varscan2
- SPTBN4 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as COSV58947253; called by muse, mutect2
- ST8SIA5 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | PolyPhen probably damaging (0.996); catalogued as COSV100165059; called by muse, mutect2
- STRA6 | c.1891G>T p.G631W | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs144308388, COSV51433473, COSV51434315; called by muse, mutect2, varscan2
- STRN3 | c.1742C>T p.T581I (on ENST00000357479 / NM_001083893.2; = p.T497I on NM_014574.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as rs199614478, COSV62579195; called by muse, mutect2, varscan2
- STX2 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99893375; called by muse, mutect2
- SYBU | c.418G>T p.V140L (on ENST00000276646 / NM_001099754.2; = p.V139L on NM_017786.6) | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV52616746; called by muse, mutect2, varscan2
- SYNDIG1 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65233975; called by muse, mutect2, varscan2
- SYNM | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV60369496; called by muse, mutect2, varscan2
- TARDBP | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV53569569; called by muse, mutect2, varscan2
- TAS2R1 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201583253, COSV66778405, COSV66779577; called by muse, mutect2, varscan2
- TBR1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67417661; called by muse, mutect2, varscan2
- TCF20 | c.5504G>T p.G1835V | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759572513, COSV59490242; called by muse, mutect2, varscan2
- TENM4 | c.4715C>A p.T1572N | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV53621365; called by muse, mutect2, varscan2
- TENT4A | c.1880G>T p.C627F | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV50095160, COSV50097781; called by muse, mutect2, varscan2
- TEX15 | c.2794C>T p.H932Y (on ENST00000256246; = p.H1315Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs745699367, COSV56344898; called by muse, mutect2, varscan2
- TEX55 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55210839; called by muse, mutect2
- TFAP2B | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53826902; called by muse, mutect2, varscan2
- TFIP11 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68020581; called by muse, mutect2, varscan2
- TGM4 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV56093523; called by muse, mutect2, varscan2
- TGM4 | c.1837C>A p.L613M | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56093531; called by muse, mutect2
- THSD1 | c.1123C>A p.P375T | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as COSV51627799; called by muse, mutect2, varscan2
- TIAF1 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV62865202; called by muse, mutect2, varscan2
- TIAM1 | c.3082C>T p.Q1028* | Nonsense Mutation (SNP) | VAF 7/107 reads (7%) | catalogued as COSV54546200; called by muse, mutect2
- TLR4 | c.2485A>C p.T829P (on ENST00000355622 / NM_138554.5; = p.T789P on NM_003266.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV62922897; called by muse, mutect2, varscan2
- TMEM132E | c.457T>A p.W153R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58696199; called by muse, mutect2, varscan2
- TMEM223 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53668065; called by muse, mutect2, varscan2
- TMEM63C | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1460044127, COSV53602856; called by muse, mutect2, varscan2
- TMTC3 | c.1802A>T p.Y601F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV57123462; called by muse, mutect2, varscan2
- TNFRSF19 | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.916); catalogued as COSV50312585; called by muse, mutect2, varscan2
- TNR | c.225G>T p.L75F | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV54880243; called by muse, mutect2, varscan2
- TRIM37 | c.2196G>T p.L732F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as rs1368202032, COSV51882984; called by muse, mutect2, varscan2
- TRIM58 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs571276238, COSV63569824, COSV63571059; called by muse, mutect2, varscan2
- TRPC6 | c.2306G>T p.S769I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV100723810; called by muse, mutect2, varscan2
- TRPM1 | c.3493G>T p.E1165* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99857003; called by muse, mutect2
- TTN | c.93181C>A p.P31061T (on ENST00000591111; = p.P23637T on NM_003319.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs74984787, COSV59989320; called by muse, mutect2, varscan2
- TTN | c.52567C>A p.L17523I (on ENST00000591111; = p.L10099I on NM_003319.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | PolyPhen benign (0.007); catalogued as COSV100636122; called by muse, mutect2
- TTN | c.27391C>A p.L9131M (on ENST00000591111; = p.L8204M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | PolyPhen possibly damaging (0.584); catalogued as COSV59989390; called by muse, mutect2, varscan2
- TTN | c.4987C>T p.P1663S (on ENST00000591111; = p.P1617S on NM_003319.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | PolyPhen benign (0.301); catalogued as COSV100636123; called by muse, mutect2, varscan2
- TUB | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV59489172, COSV59493551; called by muse, mutect2
- TUBA1B | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV60136783, COSV60138193; called by muse, mutect2, varscan2
- UBE2S | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV52740521; called by muse, mutect2, varscan2
- UBE3A | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV51663727; called by muse, mutect2
- UBQLN3 | c.1879G>C p.G627R | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100294055, COSV61163235; called by muse, mutect2, varscan2
- UBQLN3 | c.1878G>T p.M626I | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100294057; called by muse, mutect2, varscan2
- UBR4 | c.7558A>T p.S2520C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as COSV100922299; called by muse, mutect2, varscan2
- UGT8 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60417436; called by muse, mutect2, varscan2
- URB2 | c.2723G>T p.S908I | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1437797919, COSV50984751; called by muse, mutect2
- USP49 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs144313199; called by muse, mutect2
- UTP20 | c.6210G>T p.Q2070H | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.312); catalogued as COSV55375279; called by muse, mutect2, varscan2
- UTRN | c.4426G>C p.D1476H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV62332651; called by muse, mutect2, varscan2
- VEGFC | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV54596536, COSV54607406; called by muse, mutect2, varscan2
- VPS13C | c.1070A>G p.Y357C (on ENST00000644861 / NM_020821.3; = p.Y314C on NM_017684.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs766167434, COSV51129995; called by muse, varscan2
- VPS33A | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761490360, COSV57356752; called by muse, mutect2, varscan2
- VPS33B | c.477A>T p.E159D | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.192); catalogued as COSV60979779, COSV60980442; called by muse, mutect2, varscan2
- VPS72 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 72/518 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.348); catalogued as COSV63167116; called by muse, mutect2, varscan2
- VSIG8 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs142337981, COSV63652894; called by muse, mutect2
- WBP1L | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV64009573; called by muse, mutect2
- WBP2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54663402; called by muse, mutect2, varscan2
- WDR47 | c.1668G>T p.E556D (on ENST00000369962 / NM_001142551.2; = p.E557D on NM_014969.5) | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63057614; called by muse, mutect2, varscan2
- WNT7B | c.285A>T p.Q95H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59749308; called by muse, mutect2, varscan2
- XPO1 | c.2461C>G p.Q821E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV68945569; called by muse, mutect2, varscan2
- YJU2 | c.30C>G p.Y10* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV53605927; called by muse, mutect2, varscan2
- ZBTB32 | c.127C>G p.H43D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52890137; called by muse, mutect2, varscan2
- ZFHX4 | c.8780C>A p.P2927Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV50672287, COSV50678044; called by muse, mutect2, varscan2
- ZFYVE26 | c.3478A>G p.S1160G | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV61327007; called by muse, mutect2
- ZKSCAN7 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV56272371, COSV56272966; called by muse, mutect2
- ZNF100 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV59747234; called by muse, mutect2, varscan2
- ZNF106 | c.4711A>T p.T1571S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV55515574; called by muse, mutect2, varscan2
- ZNF154 | c.358A>T p.S120C | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV70744916; called by muse, mutect2, varscan2
- ZNF16 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV52763302, COSV52765814; called by muse, mutect2, varscan2
- ZNF20 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 31/167 reads (19%) | catalogued as COSV61999115; called by muse, mutect2, varscan2
- ZNF229 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV104394014, COSV52161176; called by muse, mutect2, varscan2
- ZNF257 | c.1377C>A p.Y459* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV101448185; called by muse, varscan2
- ZNF267 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 20/125 reads (16%) | catalogued as COSV56252123; called by muse, mutect2, varscan2
- ZNF320 | c.1364A>C p.H455P | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); catalogued as COSV67087907; called by muse, mutect2, varscan2
- ZNF354A | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV59982967; called by muse, mutect2, varscan2
- ZNF365 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV67925292; called by muse, mutect2, varscan2
- ZNF382 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53087468; called by muse, mutect2, varscan2
- ZNF423 | c.145G>T p.A49S (on ENST00000563137 / NM_001379286.1; = p.A41S on NM_015069.4) | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.031); catalogued as COSV52184656; called by muse, mutect2, varscan2
- ZNF526 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as COSV56629434; called by muse, mutect2, varscan2
- ZNF551 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs759391089, COSV56592204; called by muse, mutect2, varscan2
- ZNF578 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 46/231 reads (20%) | catalogued as COSV69736323, COSV69737827; called by muse, mutect2, varscan2
- ZNF71 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60147402; called by muse, mutect2, varscan2
- ZNF800 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56175014; called by muse, mutect2
- ZNF831 | c.3349G>T p.G1117W | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64039150; called by muse, mutect2, varscan2
- ZNF99 | c.2326C>T p.L776F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV68055452; called by muse, mutect2, varscan2
- ZSCAN4 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV56592199; called by muse, mutect2, varscan2
- ZSWIM3 | c.1912C>A p.L638M | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54846715; called by muse, mutect2
- ZXDA | c.2394G>T p.L798F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62387840, COSV62388431; called by muse, mutect2, varscan2
- ADSL | c.224_225delinsT p.K75Ifs*14 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | called by pindel, varscan2*
- ATOH1 | c.98del p.P33Rfs*74 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, varscan2
- C17orf78 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CDH18 | c.447del p.Q150Kfs*32 | Frame Shift Del (DEL) | VAF 48/161 reads (30%) | called by mutect2, pindel, varscan2
- DGKQ | c.1403dup p.D469Gfs*53 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- HDAC9 | c.2147T>A p.I716K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HECTD3 | c.1129del p.E377Nfs*2 | Frame Shift Del (DEL) | VAF 33/255 reads (13%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV3D-15 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NINL | c.3136del p.E1046Rfs*4 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- OR11A1 | c.496del p.Q166Sfs*2 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- OVCH1 | c.1976del p.L659Qfs*9 | Frame Shift Del (DEL) | VAF 17/115 reads (15%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.3615G>T p.Q1205H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2
- RBP3 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SMG1 | c.7729_7731del p.T2577del | In Frame Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- ZNF536 | c.2280_2282delinsT p.R761Dfs*6 | Frame Shift Del (DEL) | VAF 18/139 reads (13%) | called by pindel, varscan2*
- ABCC4 | c.3411C>T p.P1137= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100972648, COSV65311579; called by muse, mutect2, varscan2
- ADAMTS20 | c.5064C>A p.S1688= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV101240738; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2787C>A p.S929= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV54443697; called by muse, mutect2, varscan2
- AHNAK2 | c.4653G>A p.E1551= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as rs779264547, COSV60912867; called by muse, mutect2, varscan2
- AKR1E2 | c.69G>A p.V23= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as COSV53630055; called by muse, mutect2
- ANK2 | c.477T>A p.A159= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV52156073; called by muse, mutect2, varscan2
- APOB | c.6435C>A p.L2145= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV51931616; called by muse, mutect2, varscan2
- ARHGEF12 | c.3603G>A p.G1201= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV63103814; called by muse, mutect2
- ARID1B | c.5766G>T p.A1922= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs372334858, COSV99271177; called by muse, mutect2, varscan2
- ASPM | c.4719A>G p.R1573= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV54128213; called by mutect2, varscan2
- ATG4B | c.18G>T p.L6= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV60350495; called by muse, mutect2, varscan2
- ATM | c.5925T>A p.L1975= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV53737848; called by muse, mutect2, varscan2
- BCAS3 | c.1236C>T p.C412= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV66772375; called by muse, mutect2, varscan2
- BRINP2 | c.729C>T p.V243= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV64176917; called by muse, mutect2, varscan2
- C4BPB | c.336C>T p.I112= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV54691257; called by muse, mutect2
- CACNB2 | c.354G>C p.A118= (on ENST00000324631 / NM_201596.3; = p.A63= on NM_000724.4) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56619486; called by muse, mutect2, varscan2
- CADPS2 | c.1245C>T p.F415= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as COSV100466880; called by muse, mutect2, varscan2
- CARD14 | c.1761C>A p.G587= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as rs200610907; called by muse, varscan2
- CASQ1 | c.483G>A p.V161= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV63624044; called by muse, mutect2
- CCDC157 | c.180C>T p.D60= | Silent (SNP) | VAF 30/243 reads (12%) | catalogued as COSV57838575; called by muse, mutect2, varscan2
- CD1E | c.726G>A p.V242= | Silent (SNP) | VAF 19/251 reads (8%) | catalogued as COSV63770695; called by muse, mutect2
- CD6 | c.1755C>A p.P585= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV57837332, COSV57842824; called by muse, mutect2, varscan2
- CD70 | c.18G>T p.S6= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV55565978; called by mutect2, varscan2
- CDH13 | c.1320G>T p.L440= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV51809240; called by muse, mutect2, varscan2
- CFTR | c.210T>A p.I70= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV50047659; called by muse, mutect2, varscan2
- CHRM2 | c.1365C>T p.L455= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs1159399936, COSV100280400, COSV57769505; called by muse, mutect2
- CHST8 | c.843G>A p.P281= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV52858063; called by muse, mutect2, varscan2
- CIAO3 | c.219G>T p.A73= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs746463139, COSV52401662; called by muse, mutect2, varscan2
- COL16A1 | c.1239G>T p.P413= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as COSV54701305; called by muse, mutect2, varscan2
- CPN1 | c.207T>C p.P69= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV64942157; called by muse, mutect2, varscan2
- CPN2 | c.717G>A p.Q239= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV60470178; called by muse, mutect2, varscan2
- CRB1 | c.1974C>A p.I658= | Silent (SNP) | VAF 24/202 reads (12%) | catalogued as COSV66328480; called by muse, mutect2, varscan2
- CRISP3 | c.171C>A p.P57= (on ENST00000371159 / NM_001368123.1; = p.P39= on NM_006061.4) | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as COSV53819965, COSV53820909; called by muse, mutect2, varscan2
- CYLD | c.1944G>C p.L648= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV61093988; called by muse, mutect2, varscan2
- DDX10 | c.1863A>T p.T621= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV59433559; called by muse, mutect2, varscan2
- DSC2 | c.1743A>T p.T581= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs757242566, COSV51863419; called by muse, mutect2, varscan2
- DUOX2 | c.900G>A p.E300= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs765750179, COSV59908415; called by muse, mutect2
- ECT2L | c.2418C>G p.L806= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV57809947; called by muse, mutect2
- ESRRG | c.273G>T p.L91= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV63157384; called by muse, mutect2, varscan2
- FBXW12 | c.762T>C p.R254= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as COSV56483429; called by muse, mutect2
- FCGR1A | c.705C>A p.T235= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- FLG2 | c.2100A>C p.S700= | Silent (SNP) | VAF 92/765 reads (12%) | catalogued as COSV66167931; called by muse, mutect2, varscan2
- FMNL3 | c.198G>A p.L66= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as COSV53300563; called by muse, mutect2, varscan2
- FSCN3 | c.432C>A p.V144= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV50000765; called by muse, mutect2, varscan2
- GABRB3 | c.765A>T p.I255= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV54659418; called by muse, varscan2
- GABRG1 | c.975T>A p.P325= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54952499, COSV54960885; called by muse, mutect2
- GABRQ | c.510G>C p.T170= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV64781590, COSV64784271; called by muse, mutect2, varscan2
- GASK1B | c.855C>A p.I285= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV56706224; called by muse, mutect2, varscan2
- GLDC | c.2655C>A p.L885= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV58678910; called by muse, mutect2, varscan2
- GPR139 | c.681C>A p.T227= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV58502517; called by muse, mutect2, varscan2
- GPR22 | c.1245C>G p.T415= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV51747779; called by muse, mutect2
- GPX6 | c.117C>A p.T39= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100724936; called by muse, mutect2, varscan2
- HAP1 | c.246C>A p.R82= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100170123; called by muse, mutect2, varscan2
- HCN1 | c.2313G>C p.T771= | Silent (SNP) | VAF 59/121 reads (49%) | catalogued as COSV57492415, COSV57504237, COSV57520521; called by muse, mutect2, varscan2
- HS3ST5 | c.258G>T p.L86= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs768116036, COSV57138433; called by muse, mutect2, varscan2
- IGKV1-12 | c.72C>A p.I24= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs772607311; called by muse, mutect2, varscan2
- IGSF10 | c.5494C>T p.L1832= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56783961; called by muse, mutect2, varscan2
- ING3 | c.399G>T p.V133= | Silent (SNP) | VAF 57/180 reads (32%) | catalogued as COSV59950724; called by muse, mutect2, varscan2
- INTS7 | c.826C>T p.L276= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV65344101; called by muse, mutect2
- ITCH | c.1956G>T p.G652= (on ENST00000262650 / NM_001257137.3; = p.G611= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV52929561, COSV52931122; called by muse, mutect2, varscan2
- ITGA6 | c.471G>T p.L157= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV51222603; called by muse, mutect2, varscan2
- ITGAX | c.2556A>T p.P852= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV51644591; called by muse, mutect2, varscan2
- ITIH5 | c.285C>T p.I95= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV56902604; called by muse, mutect2
- KCNA4 | c.252G>A p.R84= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs561842368, COSV60251655; called by muse, mutect2, varscan2
- KCNH1 | c.1749G>T p.R583= (on ENST00000271751 / NM_172362.3; = p.R556= on NM_002238.4) | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV55077115; called by muse, mutect2, varscan2
- KCNJ16 | c.201C>T p.D67= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV52252368; called by muse, mutect2, varscan2
- KERA | c.864C>T p.H288= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV57130385; called by muse, mutect2
- KRT2 | c.540G>A p.E180= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV59010067; called by muse, mutect2, varscan2
- KRTAP5-1 | c.468C>T p.G156= | Silent (SNP) | VAF 35/299 reads (12%) | catalogued as COSV66298706; called by muse, mutect2, varscan2
- LAMA2 | c.7143C>A p.A2381= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as COSV70344464; called by muse, mutect2, varscan2
- LMOD1 | c.768A>G p.K256= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV66172383; called by muse, mutect2, varscan2
- LMX1A | c.226C>A p.R76= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV54219295; called by muse, mutect2, varscan2
- LTBP1 | c.1593C>G p.T531= (on ENST00000404816 / NM_206943.4; = p.T205= on NM_000627.4) | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV63184450; called by muse, mutect2, varscan2
- LY9 | c.1947T>A p.P649= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as COSV54433350, COSV99626230; called by muse, mutect2, varscan2
- MAN1A2 | c.1800G>A p.L600= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV62977641; called by muse, mutect2, varscan2
- MAP3K9 | c.3078A>T p.T1026= (on ENST00000554752 / NM_001284230.1; = p.T1040= on NM_033141.4) | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV67119936, COSV67120866; called by muse, mutect2, varscan2
- METTL21C | c.114C>A p.T38= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV57432515, COSV57433061; called by mutect2, varscan2
- MLH3 | c.1437A>G p.S479= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV53153994; called by muse, mutect2, varscan2
- MRPL32 | c.18G>T p.L6= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV56237538, COSV99786003; called by muse, mutect2, varscan2
- MUC17 | c.7824T>A p.S2608= | Silent (SNP) | VAF 73/595 reads (12%) | catalogued as COSV60285685; called by muse, mutect2, varscan2
- NAA15 | c.2076A>G p.L692= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1406654588, COSV56718761; called by muse, mutect2, varscan2
- NBN | c.1980A>G p.R660= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV55372508; called by muse, mutect2, varscan2
- NCAN | c.3597C>A p.P1199= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs760446655, COSV99388640; called by muse, mutect2
- NCF1 | c.630C>T p.L210= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as rs781915784; called by muse, mutect2
- NEDD9 | c.1389C>T p.L463= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV65220480, COSV65221825; called by muse, mutect2, varscan2
- NLRP5 | c.1272C>A p.P424= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101174002; called by muse, mutect2
- NLRP7 | c.846C>A p.L282= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV60173079, COSV60179249; called by muse, mutect2, varscan2
- NNT | c.2385C>T p.F795= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV52924207; called by muse, mutect2
- NRG3 | c.420C>A p.P140= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV64555774; called by muse, mutect2, varscan2
- NTAN1 | c.90C>A p.A30= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV55074071; called by muse, mutect2, varscan2
- NTAQ1 | c.480G>T p.P160= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs373023368; called by muse, mutect2, varscan2
- NUDT6 | c.753C>T p.L251= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV52649194; called by muse, mutect2
- OLFM4 | c.423T>A p.I141= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV54576760; called by muse, mutect2, varscan2
- OLFM4 | c.964C>A p.R322= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs762127606, COSV54576774, COSV54580112; called by muse, mutect2, varscan2
- OR10A7 | c.897G>T p.G299= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV58278146; called by muse, mutect2, varscan2
- OR11H6 | c.489C>A p.V163= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100209968; called by muse, mutect2
- OR2L2 | c.129C>A p.S43= | Silent (SNP) | VAF 48/484 reads (10%) | catalogued as rs771992772, COSV63551643; called by muse, mutect2
- OR2T2 | c.615G>T p.V205= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV100737835; called by mutect2, varscan2
- OR4K17 | c.573C>T p.D191= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV59647829; called by muse, mutect2, varscan2
- OR51L1 | c.210G>T p.V70= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV58624406; called by muse, mutect2, varscan2
- OR52N2 | c.9G>T p.G3= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as rs1377312414, COSV100396211, COSV57676596; called by muse, mutect2
- OR5D18 | c.430C>T p.L144= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as COSV61736787; called by muse, mutect2
- OR5D18 | c.852C>T p.P284= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV61736794; called by muse, mutect2, varscan2
- OR5M3 | c.727C>T p.L243= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV56566445; called by muse, mutect2, varscan2
- OR7G1 | c.765T>A p.A255= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99528864; called by muse, mutect2
- P3H4 | c.567G>T p.L189= | Silent (SNP) | VAF 62/462 reads (13%) | catalogued as COSV100388061; called by muse, mutect2
- PCDH10 | c.1932C>A p.V644= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs747027926, COSV52088239; called by muse, mutect2, varscan2
- PCDHB1 | c.2118C>T p.V706= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV60630363; called by muse, mutect2
- PCDHB16 | c.2142C>T p.C714= | Silent (SNP) | VAF 42/171 reads (25%) | catalogued as rs1301795129, COSV53360953; called by muse, mutect2, varscan2
- PCLO | c.13896A>T p.S4632= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV61627832; called by muse, mutect2, varscan2
- PKDCC | c.951G>T p.P317= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- PLXNB2 | c.5058C>T p.L1686= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV63781019; called by muse, mutect2
- POLR2C | c.822A>T p.I274= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV54672387; called by muse, mutect2, varscan2
- PRC1 | c.1848C>G p.T616= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs1410945233, COSV62695005; called by muse, mutect2, varscan2
- PRDM1 | c.2268G>A p.E756= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV64845015; called by muse, mutect2, varscan2
- PREB | c.1005C>T p.L335= | Silent (SNP) | VAF 7/186 reads (4%) | catalogued as COSV53205180, COSV53205545; called by muse, mutect2
- PRKCB | c.1803G>T p.R601= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV57774592; called by muse, mutect2, varscan2
- PRR22 | c.1122C>T p.T374= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100288568; called by muse, mutect2, varscan2
- PTGS1 | c.1680G>T p.T560= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs199581775, COSV56291274; called by muse, mutect2, varscan2
- PXYLP1 | c.549C>T p.I183= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV53889936; called by muse, mutect2, varscan2
- RAB34 | c.60G>C p.L20= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV56392932, COSV56393055; called by muse, mutect2, varscan2
- RCBTB1 | c.921G>T p.V307= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV51634079; called by muse, mutect2, varscan2
- RHOBTB2 | c.2097G>T p.R699= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99311412; called by muse, mutect2, varscan2
- RIT2 | c.276G>A p.G92= | Silent (SNP) | VAF 60/253 reads (24%) | catalogued as COSV56297593, COSV99950024; called by muse, mutect2, varscan2
- RTL4 | c.636C>T p.C212= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV61206174, COSV61206647; called by muse, mutect2, varscan2
- SAGE1 | c.1791C>A p.V597= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs1230749534, COSV61012425; called by muse, mutect2, varscan2
- SCUBE1 | c.135C>T p.H45= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV51810420, COSV51814888; called by muse, varscan2
- SEMA5B | c.904C>A p.R302= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV52095453; called by muse, mutect2, varscan2
- SEMG2 | c.948C>A p.I316= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV65647376; called by muse, mutect2, varscan2
- SEZ6L2 | c.156T>A p.A52= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV58098746; called by muse, mutect2, varscan2
- SLC22A14 | c.597C>T p.L199= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV56197259; called by muse, mutect2, varscan2
- SLC26A8 | c.1491A>C p.S497= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV62885440; called by muse, mutect2, varscan2
- SLC4A8 | c.1411C>A p.R471= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV60650739, COSV60651433; called by muse, mutect2
- SLC5A9 | c.1971C>T p.L657= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV52583012, COSV99361286; called by muse, mutect2
- SLC9A2 | c.1194G>T p.L398= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV52130964; called by muse, mutect2, varscan2
- SLCO5A1 | c.990C>A p.P330= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99481406; called by muse, mutect2, varscan2
- SMPD4 | c.366G>T p.V122= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV60079687; called by muse, mutect2, varscan2
- SVIL | c.2508G>A p.R836= (on ENST00000355867 / NM_021738.3; = p.R410= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV63442351, COSV63448800; called by muse, mutect2, varscan2
- TASP1 | c.63G>T p.S21= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV61812513; called by muse, mutect2, varscan2
- THSD7A | c.1947C>A p.T649= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV70263621, COSV70267222; called by muse, mutect2, varscan2
- TMEM104 | c.1095C>T p.I365= | Silent (SNP) | VAF 34/392 reads (9%) | catalogued as COSV59108844; called by muse, mutect2
- TNFRSF14 | c.249C>T p.Y83= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV63188242; called by muse, mutect2, varscan2
- TNRC18 | c.6807G>T p.T2269= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV60306991, COSV60307063; called by muse, mutect2, varscan2
- TRGV5 | c.273C>G p.P91= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs533935312; called by muse, mutect2, varscan2
- TSHZ3 | c.1717C>T p.L573= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs903678091, COSV99553220; called by muse, mutect2, varscan2
- TSHZ3 | c.1716C>A p.P572= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV53663428; called by muse, mutect2, varscan2
- TSNAXIP1 | c.91C>A p.R31= | Silent (SNP) | VAF 49/225 reads (22%) | catalogued as COSV66314771; called by muse, mutect2, varscan2
- TSPOAP1 | c.5046C>T p.Y1682= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV52106951; called by muse, mutect2, varscan2
- TTN | c.53460G>T p.V17820= (on ENST00000591111; = p.V10396= on NM_003319.4) | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV59989360; called by muse, mutect2, varscan2
- TTN | c.4986C>T p.I1662= (on ENST00000591111; = p.I1616= on NM_003319.4) | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100636125; called by muse, mutect2, varscan2
- UBA7 | c.1533G>T p.P511= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as COSV100339899, COSV61091997, COSV61093672; called by muse, mutect2, varscan2
- USH2A | c.804A>T p.G268= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV56356167; called by muse, mutect2, varscan2
- VN1R2 | c.666G>A p.L222= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV59037869; called by mutect2, varscan2
- WIPI2 | c.897C>T p.L299= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs1370017755, COSV56588417; called by muse, mutect2
- WNK1 | c.4806C>T p.P1602= (on ENST00000315939 / NM_018979.4; = p.P1355= on NM_014823.3) | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV60030444; called by muse, mutect2, varscan2
- WNT16 | c.456C>A p.T152= (on ENST00000222462 / NM_057168.2; = p.T142= on NM_016087.2) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV55975343; called by muse, mutect2, varscan2
- ZNF165 | c.246C>T p.I82= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV66102287; called by muse, mutect2
- ZNF232 | c.798G>A p.L266= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV51503002; called by muse, mutect2, varscan2
- ZNF534 | c.585G>A p.R195= (on ENST00000332323 / NM_001143939.3; = p.R182= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV56516248; called by muse, mutect2
- DPF3 | c.871+2994A>T | Intron (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100818714; called by muse, mutect2, varscan2
- GNA12 | c.526-29153G>A | Intron (SNP) | VAF 4/41 reads (10%) | catalogued as COSV51743712; called by muse, mutect2
- HMGB1P1 | n.225G>A | RNA (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.690C>A | RNA (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99683810; called by muse, mutect2, varscan2
- MIR513A1 | n.57A>G | RNA (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- MIR876 | n.19T>C | RNA (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- N4BP2L1 | c.473+79C>T | Intron (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100583138; called by muse, mutect2
- NECTIN4 | c.-1C>T | 5'UTR (SNP) | VAF 68/142 reads (48%) | catalogued as COSV100920067, COSV63512381; called by muse, mutect2, varscan2
- OR2W5 | n.828G>T | RNA (SNP) | VAF 29/171 reads (17%) | called by muse, mutect2, varscan2
- SERPINA13P | n.1039G>T | RNA (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- VN1R10P | n.525G>A | RNA (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
